Gene-level copy-number profile of specimen HCM-BROD-0213-C71-85A from HCMI case HCM-BROD-0213-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.3 years (21,286 days).
Specimen HCM-BROD-0213-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9f4ef77e-a88e-43ed-ab4f-b9f7829b184f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0213-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/70efab6a-c0d3-403a-8708-880136723d1f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 5,934; copy number 2: 47,338; copy number 3: 4,353; copy number 4: 736; copy number 5: 2; copy number 6: 2; copy number 7: 1; copy number 12: 23; copy number 13: 7.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,462,819–64,473,826, 3 genes: CR769776.2, CYP4F25P, CR769776.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 35 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,655,205–38,687,037, 2 genes, copy number 5: KRT8P20, FAM183BP.
- chr7:54,556,970–55,743,457, 28 genes, copy number 12–13 (within-gene range 4–13): VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2.
- chr20:19,757,606–20,002,459, 1 gene, copy number 7 (within-gene range 3–7): RIN2.
- chr20:20,389,530–20,738,731, 4 genes, copy number 6–12: RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P.

Autosomal genes at a single copy (total copy number 1): 5,934. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
